Surgical pathology report (de-identified scan), TCGA case TCGA-FI-A2EU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Washington University, specimen TCGA-FI-A2EU-01A (Primary Tumor).

[page 1 of 4]
lw 6/10/11		

1CD-0-3

Surgical Pathology Report Final, Corrected

Adenocarcinoma, serous, NOS
8441/3

Site: Endometrium C54.1

lw 6/10/11

SURGICAL PATHOLOGY REPORT * Amended *

Patient Name:
Address:

Service: Gynecology

Gender: F
DOB:

(Age:

Patient Type

Reported:

Other Related Clinical Data:

DIAGNOSIS:

NOTE: THIS CASE WAS AMENDED TO CORRECT COMPUTER INTERFACE PROBLEMS. THE DIAGNOSIS IS UNCHANGED.

VAGINA, POSTERIOR VAGINAL CUFF, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- ACUTE AND CHRONIC INFLAMMATION, MACROPHAGES, AND HEMOSIDERIN
- NO CARCINOMA IDENTIFIED

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

- ADENOCARCINOMA IS CONFINED TO THE ENDOMETRIUM
- ADENOCARCINOMA FOCALLY INVOLVES THE POSTERIOR LOWER UTERINE SEGMENT
- NO LYMPH VASCULAR SPACE INVASION IS IDENTIFIED

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

OVARY, LEFT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- TUBO-OVARIAN ADHESIONS

LYMPH NODES, RIGHT PELVIC, EXCISION
- NO CARCINOMA IDENTIFIED IN SIX LYMPH NODES (0/6)

LYMPH NODE, RIGHT PERIAORTIC, EXCISION
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

LYMPH NODES, LEFT PELVIC, EXCISION
- NO CARCINOMA IDENTIFIED IN FIVE LYMPH NODES (0/5)

LYMPH NODE, LEFT PERIAORTIC, EXCISION
- NO CARCINOMA IDENTIFIED IN ONE LYMPH NODE (0/1)

SOFT TISSUE, "CECAL ADHESIONS," EXCISION
- FIBROUS TISSUE WITH NO HISTOPATHOLOGIC ABNORMALITY

[page 2 of 4]
OMENTUM, OMENTECTOMY
- NO CARCINOMA IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pickup 'uterus/cervix/bilateral tubes and ovaries' consisting of a 115 gram, 8.5 cm (fundus to cervix) x 6.0 cm (cornu to cornu) x 3.0 cm (anterior to posterior) uterus with a 3.5 cm long endometrial canal. Opened in O.R. to show a 2.0 x 2.0 x 1.5 cm polypoid mass in the fundus and redundant endometrium. Tumor tissue taken for permanents," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a year old woman with a history of serous adenocarcinoma of the endometrium. Operative procedure: examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy and lymph node dissection.

Specimen(s) Received:

- A: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES
- B: RIGHT PELVIC LYMPH NODE
- C: RIGHT PERIAORTIC LYMPH NODE
- D: LEFT PELVIC LYMPH NODE
- E: LEFT PERIAORTIC LYMPH NODE
- F: CECAL ADHESION
- G: OMENTUM

Gross Description

The specimens are received in seven formalin-filled containers, each labeled. The first is labeled "uterus/cervix/bilateral tubes and ovaries."

It contains a total abdominal hysterectomy, bilateral salpingo-oophorectomy specimen, consisting of a 115 gm uterus (8.5 x 6.0 x 3.0 cm), right ovary (2.0 x 1.0 x 0.7 cm), right fallopian tube (5.5 x 0.5 x 0.5 cm), left ovary (2.0 x 1.0 x 0.5 cm), and left fallopian tube (5.0 x 0.5 x 0.5 cm). The uterine serosa is brown and smooth without adhesions or protrusions. The cervical os measures 0.4 cm. A vaginal cuff is present posteriorly (1.1 x 0.2 x 0.2 cm) and is inked blue. The ectocervix is focally hemorrhagic. On section, the cervix and lower uterine segment show a circumferential golden brown, possibly ulcerated region measuring 1.7 cm in length. A 0.6

cm Nabothian cyst is identified in the right aspect of the cervix. The endometrial cavity measures 3.5 x 1.5 cm. The endometrial cavity shows a left cornual fleshy, soft, partially hemorrhagic polyp (2.0 x 2.0 x 1.5 cm) involving both anterior and posterior uterus. The polyp is 5.5 cm from the ectocervix. On section, the polyp is pink, soft, and homogenous. It does not appear to deeply invade the uterus. The endometrial cavity, otherwise, is tan-brown and unremarkable. The right and left ovaries are tan-white and cerebriiform. On section, they are brown and unremarkable.

The fallopian tubes have a smooth brown surface and are patent. Left tubo-ovarian adhesions are identified. Labeled A1 - posterior cervix, vaginal cuff and ulcerated region; A2 - anterior cervix with ulcerated region; A3 - anterior cervix with Nabothian cysts; A4 - posterior lower uterine segment and

[page 3 of 4]
endometrium; A5 - anterior lower uterine segment and endometrium; A6 to A9 - anterior endometrium with polyp; A10 - grossly uninvolved anterior endometrium; A11 - grossly uninvolved posterior endometrium; A12 - right ovary, entirely submitted; A13 - right fallopian tube; A14 - left ovary; A15 - left tubo-ovarian adhesion and fimbria; A16- left fallopian tube. Jar 3.

The second container is labeled "right pelvic lymph node." It contains multiple pieces of fatty tissue measuring in aggregate 5.0 x 4.5 x 2.0 cm from which six lymph nodes, measuring 1.0, 1.7, 1.5, 2.3, 3.0, and 3.7 cm in greatest dimension are dissected out. Labeled B1 - two lymph nodes in entirety; B2 - one lymph node bisected; B3 - one lymph node in entirety; B4 - one lymph node bisected; B5 - one lymph node bisected. Jar 1.

The third container is labeled "right periaortic lymph node." It contains multiple fragments of yellow fatty tissue measuring in aggregate 3.0 x 2.0 x 2.0 cm from which a single lymph node measuring 1.2 x 0.4 x 0.4 cm is dissected. Labeled C - lymph node, bisected. Jar 1.

The fourth container is labeled "left pelvic lymph node." It contains multiple fragments of yellow fatty tissue measuring in aggregate 5.5 x 3.0 x 2.0 cm from which four lymph nodes, ranging from 1.3 to 2.5 cm in greatest dimension are dissected. Labeled D1 - single lymph node bisected; D2 - three lymph nodes in entirety; D3 - single lymph node bisected. Jar 1.

The fifth container is labeled "left periaortic lymph node." It contains multiple fragments of yellow fatty tissue measuring in aggregate 1 x 0.5 x 0.5 cm from which a single lymph node measuring 0.3 cm in greatest dimension is dissected. Labeled E1 - lymph node, submitted in entirety; E2- remaining tissue for lymph node search. Jar 0.

The sixth container is labeled "cecal adhesion." It contains a 0.9 x 0.2 x 0.1 cm piece of brown-gray soft tissue. Labeled F1. Jar 0.

The seventh container is labeled "omentum." It contains a 13.0 x 6.5 x 0.7 cm piece of yellow fatty tissue. No tumor implants are seen on the surface or on cut section. The tissue is yellow, lobulated, and unremarkable. Labeled G1 to G5 - random sections omentum. Jar 2.

Synopsis

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS (DO NOT USE FOR SARCOMAS)

1. THE HISTOLOGIC DIAGNOSIS IS:
Adenocarcinoma, serous papillary type
2. THE FIGO GRADE OF THE TUMOR IS:
Not applicable
3. INVASIVE TUMOR IS:
Absent (intraendometrial tumor only)
4. THE TUMOR INVADES TO A DEPTH OF 0 mm
5. THE ENDOCERVIX IS:
Uninvolved by tumor
6. LYMPHOVASCULAR SPACE INVASION BY TUMOR IS:
Absent
7. TUMOR INVASION OF ADJACENT STRUCTURES IS:
Absent
8. THE REGIONAL LYMPH NODES:
The total number of regional lymph nodes examined microscopically is:
13. The total number of regional lymph nodes involved by metastatic tumor is: 0.

Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present

[page 4 of 4]
9. "N" DATA THE REGIONAL LYMPH NODES ARE:

N0 (Free of metastases)

10. "M" DATA DISTANT METASTASES ARE:

MX (Not evaluable)

11. "T" DATA THE TUMOR IS:

TNM Categories FIGO Stages

T1a IA

Tumor

limited to endometrium

12. THE OVERALL PATHOLOGIC AJCC STAGE OF THE TUMOR IS:

Stage X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Amendments

Amended: Previous Signout Date:

Reason: This case was amended to correct computer interface problems. The diagnosis remains unchanged.

Source: NCI Genomic Data Commons file 4d9d0f2f-ab5d-49c6-8fd0-faee3a5c4248 (TCGA-FI-A2EU.95F8FB60-A533-4A37-8B4B-FC6811A77636.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).